Somatic mutation profile of tumor specimen 0DGRHE from CCDI case PBBTUW, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Vital status: Alive; Primary diagnosis: Neoplasm, uncertain whether benign or malignant; Tissue or organ of origin: Brain stem; Age at diagnosis: 3.7 years (1,346 days).
Specimen 0DGRHE: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) c24d9e15-b13a-44e8-a8c9-22bcbf292927.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DGRHT (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/62b2c84d-8af9-447f-bc51-aac0bde0d519

The open-access MAF lists 3 somatic variants for this specimen: 1 protein-altering or splice-affecting, 2 silent.
By variant classification: Silent 2, Missense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- RIPOR2 | c.878G>A p.R293Q | Missense Mutation (SNP) | VAF 285/729 reads (39%) | SIFT tolerated (0.25); PolyPhen benign (0.035); catalogued as rs745837159, COSV52427045; called by muse, mutect2, varscan2
- DMPK | c.1155G>T p.L385= | Silent (SNP) | VAF 148/434 reads (34%) | called by muse, mutect2, varscan2
- OR8D1 | c.744G>A p.V248= | Silent (SNP) | VAF 326/759 reads (43%) | catalogued as COSV63442559; called by muse, mutect2, varscan2
